Somatic mutation profile of tumor specimen C3L-07013-54 (aliquot CPT0423640002) from CPTAC case C3L-07013, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 82.4 years (30,114 days).
Specimen C3L-07013-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3d278b7-b2a7-4110-ac5a-a4d620058450.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07013-51 (Buccal Cell Normal), aliquot CPT0423740001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4329fd0b-a545-4fe6-9e0f-b8c958aa8127

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EXOC4 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs140653799; called by muse, mutect2, varscan2
- GAPVD1 | c.1301G>T p.R434I | Missense Mutation (SNP) | VAF 106/224 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.282); called by muse, varscan2
- RGS7 | c.962A>G p.E321G | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.312); called by muse, varscan2
- SLC36A1 | c.989+108C>T | Intron (SNP) | VAF 47/85 reads (55%) | called by muse, mutect2, varscan2
